Somatic mutation profile of tumor specimen MMRF_2399_1_BM_CD138pos (aliquot MMRF_2399_1_BM_CD138pos_T1_KHS5U_K14003) from MMRF case MMRF_2399, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.3 years (19,474 days).
Specimen MMRF_2399_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b17b1e8-b0f2-4b03-8deb-3e808bd9bdbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2399_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2399_1_PB_Whole_C1_KHS5U_K14002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc7002c8-3848-4f7d-909d-c351ab9fbea8

The open-access MAF lists 61 somatic variants for this specimen: 23 protein-altering or splice-affecting, 11 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 21, Missense Mutation 19, Silent 11, Intron 2, 5'UTR 2, 5'Flank 2, Nonsense Mutation 1, Frame Shift Del 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 60/134 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- DCAF8L1 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 70/71 reads (99%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs760221266; called by muse, mutect2, varscan2
- DLK2 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs774348470, COSV55095243; called by muse, mutect2, varscan2
- DNAH9 | c.7306G>A p.V2436I | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs772781273; called by muse, mutect2, varscan2
- DTYMK | c.215T>G p.F72C | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59871744; called by muse, mutect2
- FLT4 | c.89del p.P30Rfs*3 | Frame Shift Del (DEL) | VAF 13/95 reads (14%) | catalogued as COSV56098414; called by mutect2, varscan2
- IGHV2-70 | c.153T>G p.S51R | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs368987043; called by muse, mutect2, varscan2
- IGLV4-60 | c.151A>G p.S51G | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs536416304; called by muse, mutect2, varscan2
- PIK3CB | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV56688544; called by muse, mutect2, varscan2
- PLEC | c.7711C>G p.L2571V (on ENST00000322810 / NM_201380.4; = p.L2461V on NM_000445.5) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.473); catalogued as rs781885153; called by muse, mutect2, varscan2
- SECISBP2L | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 129/289 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764596929; called by muse, mutect2, varscan2
- DSN1 | c.888_908del p.G297_Q303del | In Frame Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- DUOXA1 | c.555-4C>A | Splice Region (SNP) | VAF 56/107 reads (52%) | called by muse, mutect2, varscan2
- HOOK1 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 70/133 reads (53%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.162); called by muse, varscan2
- KIF6 | c.163A>C p.S55R | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- KLHDC10 | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KMT2A | c.262T>C p.S88P | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCM3 | c.1105C>T p.L369F (on ENST00000229854 / NM_001366374.2; = p.L359F on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MCM3AP | c.2755T>C p.F919L | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- OPTC | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TNKS1BP1 | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.41337T>A p.N13779K (on ENST00000591111; = p.N6355K on NM_003319.4) | Missense Mutation (SNP) | VAF 61/139 reads (44%) | PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ACADVL | c.855G>A p.E285= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as rs201509063; called by muse, mutect2, varscan2
- CDH11 | c.867A>G p.R289= | Silent (SNP) | VAF 74/129 reads (57%) | catalogued as COSV51754995; called by muse, mutect2, varscan2
- ENPP2 | c.1167T>A p.T389= (on ENST00000075322 / NM_001040092.3; = p.T441= on NM_006209.5) | Silent (SNP) | VAF 63/120 reads (53%) | called by muse, mutect2, varscan2
- IGLV2-14 | c.207T>C p.I69= | Silent (SNP) | VAF 28/44 reads (64%) | called by muse, varscan2
- IGLV2-14 | c.303T>G p.A101= | Silent (SNP) | VAF 28/33 reads (85%) | called by muse, varscan2
- ITGAE | c.2313G>A p.E771= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- LTB4R | c.831C>T p.S277= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs1355112035; called by muse, mutect2, varscan2
- OAS3 | c.2325G>A p.K775= | Silent (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- PTPRF | c.1380C>T p.N460= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs766810518; called by muse, mutect2, varscan2
- SLC28A3 | c.369G>C p.L123= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- SRP72 | c.1029C>A p.I343= | Silent (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- AK9 | c.3633+13del | Intron (DEL) | VAF 5/47 reads (11%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- ANXA2 | c.-146G>A | 5'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- CHODL | c.*1216C>T | 3'UTR (SNP) | VAF 38/71 reads (54%) | called by muse, mutect2, varscan2
- CRIP2 | chr14:105473228 C>T | 5'Flank (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2
- DZIP1 | c.*717G>T | 3'UTR (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- FEZ1 | chr11:125497488 C>T | 5'Flank (SNP) | VAF 12/25 reads (48%) | catalogued as rs1245830657; called by muse, mutect2, varscan2
- FOXI2 | c.*321C>A | 3'UTR (SNP) | VAF 52/171 reads (30%) | called by muse, mutect2, varscan2
- FRMD5 | c.*2121C>G | 3'UTR (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- GABRA1 | c.-15-89A>C | Intron (SNP) | VAF 142/270 reads (53%) | called by muse, mutect2, varscan2
- H2AC6 | c.-17A>T | 5'UTR (SNP) | VAF 23/178 reads (13%) | catalogued as rs777951056, COSV100019976, COSV100020081; called by muse, mutect2
- HLA-DQA1 | c.*142G>A | 3'UTR (SNP) | VAF 292/370 reads (79%) | called by muse, mutect2, varscan2
- HUNK | c.*1445C>T | 3'UTR (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2
- MEX3C | c.*1215_*1216del | 3'UTR (DEL) | VAF 50/135 reads (37%) | called by mutect2, pindel, varscan2
- P2RY1 | c.*647G>A | 3'UTR (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2, varscan2
- PCF11 | c.*668C>T | 3'UTR (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- PHYH | c.*51T>C | 3'UTR (SNP) | VAF 106/193 reads (55%) | called by muse, mutect2, varscan2
- PLCXD3 | c.*5425C>A | 3'UTR (SNP) | VAF 42/83 reads (51%) | called by muse, mutect2, varscan2
- RAB20 | c.*258G>A | 3'UTR (SNP) | VAF 78/151 reads (52%) | called by muse, mutect2, varscan2
- RASSF9 | c.*102T>C | 3'UTR (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- SFRP4 | c.*348C>G | 3'UTR (SNP) | VAF 47/93 reads (51%) | called by muse, mutect2, varscan2
- SHOC2 | c.*1165G>C | 3'UTR (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- SLC16A1 | c.*794A>T | 3'UTR (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- SLC9A3 | c.*1833G>A | 3'UTR (SNP) | VAF 98/184 reads (53%) | called by muse, mutect2, varscan2
- ST8SIA5 | c.*775G>A | 3'UTR (SNP) | VAF 13/69 reads (19%) | catalogued as rs988078485; called by muse, mutect2
- TENM4 | c.*4255C>T | 3'UTR (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- TSPAN9 | c.*222T>A | 3'UTR (SNP) | VAF 39/79 reads (49%) | called by muse, varscan2
- TUSC3 | c.*1483A>C | 3'UTR (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
